Somatic mutation profile of tumor specimen TCGA-CV-7421-01A (aliquot TCGA-CV-7421-01A-11D-2078-08) from TCGA case TCGA-CV-7421, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 76.6 years (27,961 days).
Specimen TCGA-CV-7421-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fac8037-9b9a-4ea8-b713-c57c9c0272ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7421-10A (Blood Derived Normal), aliquot TCGA-CV-7421-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dd1d7c4-5e7e-4ec7-a8e4-43e21ff3a6f5

The open-access MAF lists 65 somatic variants for this specimen: 46 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 38, Silent 19, Splice Region 3, Frame Shift Ins 2, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CB | c.3200A>T p.D1067V | Missense Mutation (SNP) | VAF 40/108 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56683107, COSV56689255; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 10/21 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AUP1 | c.1192A>G p.R398G | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99239666; called by muse, mutect2, varscan2
- BCOR | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.717); catalogued as COSV100653305, COSV100654154; called by muse, mutect2, varscan2
- CALCB | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs369737294; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1627-1G>A p.X543_splice | Splice Site (SNP) | VAF 15/78 reads (19%) | catalogued as COSV100575438; called by muse, mutect2, varscan2
- CYRIA | c.917C>G p.T306R | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100838365; called by muse, mutect2, varscan2
- FAM135B | c.2321C>A p.P774H | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99423840; called by muse, mutect2
- GPSM2 | c.1444A>G p.I482V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99915234; called by muse, mutect2, varscan2
- HIRA | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as rs1463800504, COSV99600334; called by mutect2, varscan2
- IGLV3-16 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.359); catalogued as rs566742180; called by muse, mutect2, varscan2
- KPRP | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs745652034, COSV100908633; called by muse, mutect2, varscan2
- LRP2 | c.3625G>A p.G1209S | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99788409; called by muse, mutect2, varscan2
- LRPPRC | c.575A>G p.N192S | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV99580589; called by muse, mutect2, varscan2
- LRRC4C | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.337); catalogued as COSV53435904; called by muse, mutect2, varscan2
- MAP7D2 | c.1228C>A p.Q410K | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.334); catalogued as COSV65529949; called by muse, mutect2, varscan2
- MC2R | c.431T>C p.M144T | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs770934270, COSV100562996; called by muse, mutect2, varscan2
- MCM3AP | c.877A>G p.R293G | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99386922; called by muse, mutect2, varscan2
- MRPL53 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV99252124; called by muse, mutect2
- MUC5B | c.12773C>G p.T4258S | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.078); catalogued as COSV101500307; called by muse, mutect2
- NDRG3 | c.365C>T p.P122L (on ENST00000349004 / NM_032013.4; = p.P110L on NM_022477.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as COSV100675374; called by muse, mutect2, varscan2
- NHLRC3 | c.632C>G p.A211G | Missense Mutation (SNP) | VAF 82/174 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101098972; called by muse, mutect2, varscan2
- OR11H6 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as rs146448571; called by muse, mutect2, varscan2
- OR2L3 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100741968; called by muse, mutect2
- OR4K17 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV100210653; called by muse, mutect2, varscan2
- PLEKHA8 | c.1362G>T p.A454= | Splice Region (SNP) | VAF 12/26 reads (46%) | catalogued as rs757950570, COSV99321766; called by muse, mutect2, varscan2
- POLK | c.1529G>A p.G510D | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99605919; called by muse, mutect2, varscan2
- POLR1A | c.4904C>T p.A1635V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs767586683, COSV55694719; called by muse, mutect2, varscan2
- PPIH | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.089); catalogued as COSV100501326; called by muse, mutect2, varscan2
- RABGAP1L | c.2120A>T p.K707M | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99270141; called by muse, mutect2, varscan2
- RARA | c.630G>A p.T210= | Splice Region (SNP) | VAF 4/8 reads (50%) | catalogued as COSV99564989; called by muse, mutect2
- RFC1 | c.1732G>C p.E578Q | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.067); catalogued as COSV100567671; called by muse, mutect2, varscan2
- RPL10 | c.471C>G p.F157L | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV99185937; called by muse, mutect2
- RWDD2B | c.588T>A p.H196Q | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54501549; called by muse, mutect2, varscan2
- SHCBP1L | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.52); catalogued as COSV100772522; called by muse, mutect2, varscan2
- SLC5A2 | c.1379C>G p.S460C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV57890622; called by muse, mutect2, varscan2
- SOBP | c.2432A>G p.D811G | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs1210204094, COSV100433124; called by muse, mutect2, varscan2
- SPATA7 | c.689C>G p.S230C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1248055951, COSV99247963; called by muse, mutect2, varscan2
- SUSD1 | c.372A>T p.T124= | Splice Region (SNP) | VAF 43/283 reads (15%) | catalogued as COSV100813292; called by muse, mutect2, varscan2
- TCF21 | c.29A>G p.E10G | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99399632; called by muse, mutect2
- TMEM187 | c.47G>C p.G16A | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100890165; called by muse, varscan2
- TRIM42 | c.1432G>T p.D478Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99648347; called by muse, varscan2
- GABRE | c.647-14_655del p.X216_splice | Splice Site (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- GTF2H4 | c.340_360del p.F114_I120del | In Frame Del (DEL) | VAF 13/119 reads (11%) | called by mutect2, pindel
- LEMD2 | c.1239_1240dup p.M414Rfs*3 | Frame Shift Ins (INS) | VAF 25/204 reads (12%) | called by mutect2, pindel, varscan2
- RSPH3 | c.1059_1060dup p.N354Rfs*32 (on ENST00000252655; = p.N212Rfs*32 on NM_031924.8) | Frame Shift Ins (INS) | VAF 10/74 reads (14%) | called by mutect2, pindel, varscan2
- ABCA9 | c.2211C>A p.A737= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100383101; called by muse, mutect2, varscan2
- BTBD1 | c.714T>C p.S238= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV99915465; called by muse, mutect2, varscan2
- CHRNB3 | c.684C>G p.V228= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV99251158; called by muse, varscan2
- CHRNB3 | c.723C>A p.I241= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV99251160; called by muse, varscan2
- CYYR1 | c.423G>A p.Q141= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV54832130; called by muse, mutect2, varscan2
- DYNC1H1 | c.10776C>A p.P3592= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV100794864; called by muse, mutect2, varscan2
- EIF2AK2 | c.1149C>T p.G383= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs764479308, COSV99240654; called by muse, mutect2, varscan2
- FABP2 | c.51G>A p.K17= | Silent (SNP) | VAF 32/185 reads (17%) | catalogued as COSV99916904; called by muse, mutect2, varscan2
- GAPDH | c.477C>T p.P159= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV99975508; called by muse, mutect2, varscan2
- NAPRT | c.1062C>T p.V354= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV99434829; called by muse, mutect2, varscan2
- NCAN | c.2400G>C p.G800= | Silent (SNP) | VAF 12/173 reads (7%) | catalogued as rs1037915851, COSV99387210; called by muse, mutect2
- PRKCG | c.792G>A p.S264= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs756464178, COSV99668988, COSV99669461; called by muse, mutect2, varscan2
- PTPN13 | c.4971G>A p.G1657= (on ENST00000411767 / NM_080683.3; = p.G1638= on NM_006264.3) | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100364727; called by muse, mutect2, varscan2
- RAPSN | c.579C>G p.V193= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100100201; called by muse, mutect2, varscan2
- SLC6A3 | c.741C>G p.V247= | Silent (SNP) | VAF 7/101 reads (7%) | catalogued as COSV99548288; called by muse, mutect2
- SOAT2 | c.1320C>T p.F440= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs201335480, COSV56859558; called by muse, mutect2, varscan2
- SON | c.2076T>A p.P692= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV99278278; called by muse, mutect2, varscan2
- SORL1 | c.1122C>T p.I374= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV52753406; called by muse, mutect2
- TSHZ1 | c.3123C>T p.L1041= (on ENST00000580243 / NM_001308210.2; = p.L996= on NM_005786.6) | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100433649; called by muse, varscan2
